Somatic mutation profile of tumor specimen TCGA-HT-7607-01A (aliquot TCGA-HT-7607-01A-11D-2086-08) from TCGA case TCGA-HT-7607, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 61.8 years (22,585 days).
Specimen TCGA-HT-7607-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0528741d-58b5-4b03-ab7d-3e39360d5110.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7607-10A (Blood Derived Normal), aliquot TCGA-HT-7607-10A-01D-2086-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d9f41e8-55ad-40d4-8bc4-a50091e49ffc

The open-access MAF lists 30 somatic variants for this specimen: 25 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 23, Silent 5, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 19/138 reads (14%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ING1 | c.1015C>T p.R339* | Nonsense Mutation (SNP) | VAF 14/57 reads (25%) | hotspot (GDC flag); catalogued as COSV58167363; called by muse, varscan2
- MAX | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 22/88 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52414939; called by muse, mutect2, varscan2
- PIK3CA | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 23/133 reads (17%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen possibly damaging (0.655); catalogued as rs1057519925, COSV55873816, COSV55874585; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACAN | c.4349G>T p.G1450V | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV61367473; called by muse, varscan2
- AOC1 | c.1453G>A p.V485I | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs765084312, COSV62870429; called by muse, mutect2, varscan2
- COL27A1 | c.4000G>A p.E1334K | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as rs777108972, COSV61929932; called by muse, mutect2, varscan2
- GABRA3 | c.49C>G p.L17V | Missense Mutation (SNP) | VAF 35/171 reads (20%) | SIFT tolerated, low confidence (0.29); PolyPhen possibly damaging (0.899); catalogued as COSV64795919, COSV64803902; called by muse, mutect2, varscan2
- GMPR | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.044); catalogued as COSV52474948; called by muse, mutect2, varscan2
- HCFC1 | c.551T>G p.V184G | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV60076514; called by muse, mutect2, varscan2
- HCN4 | c.2294C>T p.A765V | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV56086587; called by muse, mutect2, varscan2
- KIAA1191 | c.227G>A p.S76N | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.022); catalogued as COSV53799831; called by muse, mutect2, varscan2
- OFD1 | c.2918C>T p.S973L | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1801618, COSV57424089; called by muse, varscan2
- PA2G4 | c.868C>T p.R290W | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.185); catalogued as COSV57567746, COSV57570092; called by muse, mutect2, varscan2
- PDCD4 | c.77G>A p.G26D | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.058); catalogued as rs772371476, COSV54525131; called by muse, mutect2, varscan2
- PHF6 | c.410A>G p.N137S | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.037); catalogued as COSV59705841; called by muse, mutect2
- PLEKHM1 | c.973G>A p.G325R | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as rs760190921, COSV69599346; called by muse, mutect2, varscan2
- POT1 | c.547G>T p.V183L | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV62933692; called by muse, mutect2, varscan2
- TRRAP | c.1825G>A p.G609R | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.023); catalogued as COSV62852312; called by muse, mutect2, varscan2
- VIL1 | c.1273G>A p.D425N | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.99); catalogued as rs371206014, COSV50288180; called by muse, mutect2
- WDR27 | c.1460C>T p.S487F | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61214506; called by muse, mutect2, varscan2
- ZP2 | c.1097T>C p.I366T | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as rs142277591; called by muse, mutect2, varscan2
- MUC3A | c.7142C>G p.T2381S | Missense Mutation (SNP) | VAF 76/470 reads (16%) | SIFT tolerated, low confidence (0.34); called by mutect2, varscan2
- PSME4 | c.3850G>T p.V1284F | Missense Mutation (SNP) | VAF 11/169 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.021); called by muse, mutect2
- ZNF292 | c.1683_1684del p.K562Tfs*8 | Frame Shift Del (DEL) | VAF 7/41 reads (17%) | called by mutect2, pindel, varscan2
- AHRR | c.393G>A p.T131= | Silent (SNP) | VAF 28/131 reads (21%) | catalogued as rs766764585, COSV57092046; called by muse, mutect2, varscan2
- FRMPD4 | c.1002C>T p.A334= | Silent (SNP) | VAF 41/184 reads (22%) | catalogued as COSV66221524; called by muse, mutect2, varscan2
- INAVA | c.1317C>T p.P439= | Silent (SNP) | VAF 37/257 reads (14%) | catalogued as COSV66256611; called by muse, mutect2, varscan2
- NLGN4X | c.2049G>A p.A683= | Silent (SNP) | VAF 27/127 reads (21%) | catalogued as rs772348674, COSV52032697; ClinVar: benign; called by muse, mutect2, varscan2
- PHF13 | c.840C>G p.S280= | Silent (SNP) | VAF 19/96 reads (20%) | catalogued as COSV50011587; called by muse, mutect2, varscan2
